Somatic mutation profile of tumor specimen TCGA-P3-A6T5-01A (aliquot TCGA-P3-A6T5-01A-11D-A34J-08) from TCGA case TCGA-P3-A6T5, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower gum; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 79.3 years (28,977 days).
Specimen TCGA-P3-A6T5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12a62ada-d4f4-4805-9195-7f6858bec40e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6T5-10A (Blood Derived Normal), aliquot TCGA-P3-A6T5-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86a122d2-0ffa-4dd4-9b64-e35fabc0fc87

The open-access MAF lists 244 somatic variants for this specimen: 173 protein-altering or splice-affecting, 69 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 69, Nonsense Mutation 7, Splice Site 3, Frame Shift Del 3, In Frame Del 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 35/64 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs483352697, CM984587, COSV52667931, COSV52674826, COSV52678297; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.1567G>T p.V523L | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV53052105, COSV99491224; called by muse, mutect2
- ACAD8 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99844070; called by muse, mutect2, varscan2
- ACIN1 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV52973774; called by muse, mutect2, varscan2
- ADAM10 | c.1160A>T p.H387L | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99545501; called by muse, mutect2, varscan2
- AKAP6 | c.5095C>G p.L1699V | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.746); catalogued as COSV99798049; called by muse, mutect2, varscan2
- ANKEF1 | c.428A>T p.N143I | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101000976; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1126C>G p.L376V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99781963; called by muse, mutect2, varscan2
- ANKRD20A4P | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 89/380 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100628391; called by muse, mutect2, varscan2
- ARHGAP33 | c.2738G>A p.G913D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV99137533; called by muse, mutect2, varscan2
- ATP1A1 | c.2660G>C p.R887P | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99814138; called by muse, varscan2
- ATP2C1 | c.1804A>G p.M602V | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1002638794, COSV100146229; called by muse, mutect2, varscan2
- ATP2C2 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99297429; called by muse, mutect2, varscan2
- ATP6V0A4 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.598); catalogued as COSV100022593, COSV59477638; called by muse, mutect2, varscan2
- ATP6V0C | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53550634; called by muse, mutect2, varscan2
- B4GALT4 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100785753; called by muse, mutect2
- BAZ2B | c.3180G>C p.K1060N | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99680857; called by muse, varscan2
- BCAS2 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV101058485; called by muse, mutect2, varscan2
- BIRC6 | c.5536G>A p.D1846N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs1346806581, COSV101427821; called by muse, mutect2
- BTN1A1 | c.886A>G p.K296E | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs749301249, COSV99764154; called by muse, mutect2
- C7orf31 | c.684+1G>C p.X228_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99383727; called by mutect2, varscan2
- CACNA1H | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192663419, COSV100670705; called by muse, mutect2
- CCDC102B | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs774612533, COSV100102049, COSV100102573; called by muse, mutect2, varscan2
- CCDC7 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99511287; called by muse, mutect2
- CDC16 | c.1399T>C p.Y467H | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99372682; called by muse, mutect2
- CENPF | c.8283A>T p.K2761N | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as COSV100871478; called by muse, mutect2, varscan2
- CEP128 | c.2772G>T p.E924D | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99823578; called by muse, mutect2, varscan2
- CFAP47 | c.4758C>A p.D1586E | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV100544880; called by muse, mutect2, varscan2
- CGNL1 | c.2201A>C p.Q734P | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99847412; called by muse, mutect2, varscan2
- CMC4 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100749832; called by muse, mutect2, varscan2
- CNKSR2 | c.1508G>C p.S503T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as rs1381130395, COSV99667269; called by muse, mutect2, varscan2
- COL2A1 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.95); catalogued as COSV100475419, COSV61535352; called by muse, mutect2, varscan2
- CRYGD | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs144372987, COSV52205030; called by muse, mutect2, varscan2
- CUL4B | c.2063C>A p.P688Q | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100340107; called by muse, mutect2, varscan2
- CYB5B | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV100327672; called by muse, mutect2, varscan2
- CYP26A1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99814550; called by muse, mutect2, varscan2
- DAP3 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.609); catalogued as COSV58019683, COSV58019851, COSV58021842; called by muse, mutect2, varscan2
- DEUP1 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as rs766158479, COSV99976429; called by muse, mutect2, varscan2
- DPF3 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100818412; called by muse, mutect2
- DPP10 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100058206; called by muse, mutect2, varscan2
- EGFR | c.2654C>G p.S885* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99286603; called by muse, mutect2, varscan2
- EIF4G3 | c.974C>A p.P325H | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs780287218, COSV99943130; called by muse, mutect2
- ELMO1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs146510671; called by muse, mutect2, varscan2
- ELN | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52710550, COSV52714958; called by muse, mutect2, varscan2
- FAM227B | c.27G>T p.R9S | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV100174412, COSV54813880; called by muse, mutect2, varscan2
- FAM47A | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100649706; called by muse, mutect2, varscan2
- FAT3 | c.9431C>G p.T3144R | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs571920220, COSV99961564; called by muse, mutect2, varscan2
- FBXL7 | c.1414C>A p.R472S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100309015, COSV61646231; called by muse, mutect2, varscan2
- FNDC4 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV53020874; called by muse, mutect2
- FRS3 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs200242322, COSV99442576; called by muse, mutect2, varscan2
- FXYD5 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779297539, COSV61569465; called by muse, mutect2, varscan2
- GANAB | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100647804; called by muse, mutect2
- GCNA | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 75/506 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as rs748837590, COSV101032369, COSV65468065; called by muse, varscan2
- GIPR | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221375035, COSV54427024; called by muse, mutect2, varscan2
- GMPR2 | c.720G>A p.M240I (on ENST00000355299 / NM_001351022.2; = p.M258I on NM_016576.5) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99945255; called by muse, mutect2, varscan2
- GNA14 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758196305, COSV59028817; called by muse, mutect2, varscan2
- GPR155 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789661; called by muse, mutect2, varscan2
- GPR52 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); catalogued as COSV99267388; called by muse, mutect2
- GPR52 | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 22/364 reads (6%) | catalogued as COSV99267390; called by muse, mutect2
- GRIK2 | c.2699G>C p.R900T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as COSV100022809, COSV100022818; called by muse, mutect2
- H2AC21 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV100479673; called by muse, mutect2
- HDAC9 | c.1330A>G p.R444G | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101286074; called by muse, mutect2, varscan2
- HIVEP1 | c.3696C>G p.I1232M | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101044642; called by muse, mutect2
- HUWE1 | c.12643A>G p.M4215V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99470532; called by muse, mutect2, varscan2
- IGLV3-21 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.662); catalogued as rs566631800; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1856G>C p.R619T | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV100780701; called by muse, mutect2, varscan2
- IMMP1L | c.23A>G p.K8R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as COSV99540626; called by muse, mutect2, varscan2
- ITSN2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV61947390; called by muse, mutect2
- KANK4 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.118); catalogued as rs1315873891, COSV100586989; called by muse, mutect2, varscan2
- KBTBD2 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs957134147, COSV100406370; called by muse, mutect2
- KLHL4 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV100909076; called by muse, mutect2, varscan2
- KLKB1 | c.1490-1G>C p.X497_splice | Splice Site (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99249592, COSV99250080; called by muse, mutect2, varscan2
- KMT5C | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99726045; called by muse, mutect2, varscan2
- KSR1 | c.2204C>G p.S735* (on ENST00000644974 / NM_001367810.1; = p.S620* on NM_014238.2) | Nonsense Mutation (SNP) | VAF 22/247 reads (9%) | catalogued as COSV99257940; called by muse, mutect2
- LCP1 | c.1281C>A p.F427L | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as COSV100549654; called by muse, mutect2
- LDHAL6A | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs201761125; called by muse, mutect2, varscan2
- LIG4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100799684; called by muse, mutect2, varscan2
- LRCH4 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV59645273; called by muse, mutect2, varscan2
- LRP1B | c.10100G>C p.G3367A | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101251916; called by muse, mutect2
- LRRC55 | c.717C>G p.F239L | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV101546696; called by muse, mutect2
- LRRN3 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV100067482, COSV57817821; called by muse, mutect2, varscan2
- MADD | c.3806G>C p.G1269A | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100210981; called by muse, mutect2, varscan2
- MAP3K21 | c.965C>G p.S322C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100786210; called by muse, mutect2
- MAP3K8 | c.1277C>A p.S426Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs1194945390, COSV99551920; called by muse, mutect2
- METTL18 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99609365; called by muse, mutect2
- MMGT1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs782324212, COSV99045474; called by muse, mutect2, varscan2
- MVD | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs752905131, COSV56331832; called by muse, mutect2, varscan2
- MYH6 | c.1597T>C p.S533P | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100676263; called by muse, mutect2, varscan2
- MYO1A | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100270544; called by muse, mutect2, varscan2
- NT5DC1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV100126266; called by muse, mutect2, varscan2
- OPN1SW | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.091); catalogued as COSV99975434; called by muse, mutect2, varscan2
- OR10V1 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs200769474, COSV55695543; called by muse, mutect2, varscan2
- OSMR | c.2139C>G p.F713L | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57082082, COSV99952607; called by muse, mutect2, varscan2
- PCDHA8 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100969361, COSV65328168; called by muse, mutect2, varscan2
- PCDHB6 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99169903; called by muse, mutect2, varscan2
- PCDHGA5 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.082); catalogued as COSV99530036; called by muse, mutect2, varscan2
- PELP1 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV99342480; called by muse, mutect2, varscan2
- PHLDA2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs878960560, COSV100045198; called by muse, mutect2, varscan2
- PLAA | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101263481; called by muse, mutect2
- PLCH2 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99615481; called by muse, mutect2, varscan2
- PLXDC2 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.099); catalogued as COSV65905341; called by muse, mutect2, varscan2
- PPP1R3C | c.705C>A p.C235* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as COSV99490840; called by muse, mutect2, varscan2
- PTGDR | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.227); catalogued as rs756509372, COSV100035425; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.212C>T p.S71F (on ENST00000421990 / NM_001136042.2; = p.S53F on NM_025267.3) | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as rs755317118, COSV100799185; called by muse, mutect2, varscan2
- PXDN | c.1201A>T p.N401Y | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99412216; called by muse, mutect2, varscan2
- RBPJL | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV100643429, COSV100643541; called by muse, mutect2, varscan2
- REV3L | c.5827G>A p.D1943N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100724831; called by muse, mutect2, varscan2
- RNF40 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100221893; called by muse, mutect2
- RXFP3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs763707487, COSV57505861; called by muse, mutect2
- SACS | c.6553A>G p.S2185G | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.637); catalogued as COSV101207163; called by muse, mutect2, varscan2
- SEC23A | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); catalogued as rs572679988, COSV56980039; called by muse, mutect2, varscan2
- SEL1L2 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs747921740, COSV99532517; called by muse, mutect2, varscan2
- SEMA4A | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as COSV100740421; called by muse, mutect2, varscan2
- SEMA6D | c.2996G>A p.G999E (on ENST00000316364 / NM_153618.2; = p.G937E on NM_020858.2) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.175); catalogued as COSV60375251; called by muse, mutect2, varscan2
- SEZ6L | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as COSV99961288; called by muse, mutect2, varscan2
- SLC12A4 | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs768395839, COSV100311196; called by muse, mutect2, varscan2
- SLC25A30 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV100181221; called by muse, mutect2, varscan2
- SLC25A42 | c.260T>A p.L87H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV100588007; called by muse, mutect2
- SLC6A19 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 91/275 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs751744792, COSV100443207; called by muse, mutect2, varscan2
- SLFN5 | c.1586T>C p.L529P | Missense Mutation (SNP) | VAF 90/152 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100249485; called by muse, mutect2, varscan2
- SMAD4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555685158, COSV100747458, COSV61694586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMU1 | c.874A>T p.K292* | Nonsense Mutation (SNP) | VAF 89/267 reads (33%) | catalogued as COSV101238497; called by muse, mutect2, varscan2
- SMUG1 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as rs766141046, COSV99679308; called by muse, mutect2, varscan2
- SNTB1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866729656, COSV101179704; called by muse, mutect2, varscan2
- SOCS5 | c.907T>G p.L303V | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV100124981; called by muse, mutect2, varscan2
- SP140 | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV59447545; called by muse, mutect2
- SPEG | c.7099G>A p.E2367K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV100403200; called by muse, mutect2
- STEAP3 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs768487970, COSV61530530; called by muse, mutect2, varscan2
- SULF2 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100736969; called by muse, mutect2, varscan2
- SUV39H1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs1557010351, COSV100551674, COSV100551800; called by muse, mutect2, varscan2
- SVEP1 | c.8808C>A p.N2936K | Missense Mutation (SNP) | VAF 241/350 reads (69%) | SIFT tolerated (0.87); PolyPhen benign (0.038); catalogued as COSV99928222; called by muse, mutect2, varscan2
- TAS2R40 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV101282973; called by muse, mutect2, varscan2
- TBC1D22B | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs771598747, COSV100996650; called by muse, mutect2, varscan2
- TBC1D2B | c.2628G>C p.L876F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100316789; called by muse, mutect2
- TENM1 | c.7303G>C p.G2435R | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948965; called by muse, mutect2, varscan2
- TESPA1 | c.1285G>A p.E429K (on ENST00000316577 / NM_001098815.3; = p.E291K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.429); catalogued as rs753897433, COSV100344831; called by muse, varscan2
- TESPA1 | c.1232G>C p.R411T (on ENST00000316577 / NM_001098815.3; = p.R273T on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); catalogued as COSV100344834; called by muse, varscan2
- TEX15 | c.1969G>C p.E657Q (on ENST00000256246; = p.E1040Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV99820662; called by muse, mutect2
- TEX47 | c.102A>T p.Q34H | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV99787160; called by muse, mutect2, varscan2
- TIMELESS | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1342254701, COSV99973567; called by muse, mutect2, varscan2
- TKTL1 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99473681; called by muse, mutect2, varscan2
- TMEM38A | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 47/417 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs878950283, COSV99495096; called by muse, mutect2, varscan2
- TNXB | c.4194G>C p.Q1398H (on ENST00000647633; = p.Q1151H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.153); catalogued as COSV100925764; called by muse, mutect2
- TPO | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139292269; called by muse, mutect2, varscan2
- TRPC6 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.011); catalogued as rs779132904, COSV60259702; called by muse, mutect2, varscan2
- TRPM8 | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs200217624; called by muse, mutect2, varscan2
- TSPAN32 | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99477961; called by muse, mutect2, varscan2
- TTC25 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as rs375888994; called by muse, mutect2
- TUBB | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.701); catalogued as COSV100013245; called by muse, mutect2
- UBTF | c.1048-1G>C p.X350_splice | Splice Site (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100255757, COSV57186156; called by muse, mutect2, varscan2
- UBTF | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100255760; called by muse, mutect2
- UGT3A1 | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV99954247; called by muse, mutect2, varscan2
- UPF1 | c.2772C>G p.F924L (on ENST00000599848 / NM_001297549.2; = p.F913L on NM_002911.4) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99438745, COSV99439563; called by muse, mutect2
- USP40 | c.896G>C p.G299A | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99295739; called by muse, mutect2
- VPS13D | c.10008G>A p.M3336I | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV99165415; called by muse, mutect2, varscan2
- VSTM1 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs933660144, COSV100618657; called by muse, mutect2, varscan2
- VWF | c.6141G>A p.M2047I | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV99777878; called by muse, mutect2, varscan2
- XIAP | c.86G>C p.R29T | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848815, COSV63021922; called by muse, mutect2, varscan2
- ZBED9 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs541386862, COSV71729503; called by muse, mutect2, varscan2
- ZFC3H1 | c.1227A>C p.Q409H | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV101110295; called by muse, mutect2, varscan2
- ZHX1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 40/405 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99933464; called by muse, mutect2
- ZNF639 | c.1193C>G p.T398R | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100418373; called by muse, mutect2, varscan2
- ZNF687 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV99649266; called by muse, mutect2, varscan2
- ZNF687 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55015320; called by muse, mutect2, varscan2
- ZNF831 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.828); catalogued as rs781462631, COSV100925748, COSV64041481; called by mutect2, varscan2
- CFAP410 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- CYFIP1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ELP5 | c.306del p.P103Rfs*5 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- HAS2 | c.558dup p.W187Mfs*26 | Frame Shift Ins (INS) | VAF 83/396 reads (21%) | called by mutect2, pindel, varscan2
- IGLV5-52 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 37/367 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- LMBRD2 | c.1071_1073del p.P358del | In Frame Del (DEL) | VAF 11/108 reads (10%) | called by mutect2, pindel, varscan2
- MAGEA10 | c.240_241delinsG p.P81Qfs*9 | Frame Shift Del (DEL) | VAF 22/213 reads (10%) | called by pindel, varscan2*
- MAP3K15 | c.1977del p.G661Afs*12 | Frame Shift Del (DEL) | VAF 27/218 reads (12%) | called by mutect2, pindel, varscan2
- AKNA | c.195C>T p.H65= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV99799596; called by muse, mutect2
- AKT1 | c.870C>T p.I290= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100837936, COSV62575571; called by muse, mutect2
- ANAPC2 | c.237G>A p.L79= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100118866; called by muse, mutect2, varscan2
- ARAP1 | c.2328T>C p.L776= (on ENST00000393609 / NM_001040118.2; = p.L531= on NM_015242.4) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100501526; called by muse, mutect2, varscan2
- ARHGEF12 | c.1917A>G p.E639= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100754629; called by muse, mutect2, varscan2
- BCORL1 | c.1710C>A p.A570= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV99498361; called by muse, mutect2, varscan2
- BRSK1 | c.225G>A p.L75= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100510273; called by muse, mutect2, varscan2
- CD109 | c.2064G>A p.K688= | Silent (SNP) | VAF 86/158 reads (54%) | catalogued as COSV99752496; called by muse, mutect2, varscan2
- CDH13 | c.1485G>T p.V495= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99222141; called by muse, mutect2, varscan2
- CFC1 | c.192C>T p.S64= | Silent (SNP) | VAF 11/241 reads (5%) | catalogued as rs1235983859, COSV52090306, COSV99035000; called by muse, mutect2
- CLEC12B | c.540G>A p.V180= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100138885; called by muse, mutect2
- CRYBA4 | c.315G>A p.S105= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as rs761401096, COSV100697746; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1044G>A p.K348= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as COSV100174496; called by muse, mutect2, varscan2
- CYP4Z1 | c.702C>T p.D234= | Silent (SNP) | VAF 20/385 reads (5%) | catalogued as COSV100497511; called by muse, mutect2
- DMTF1 | c.1317T>C p.H439= | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as rs149430074; called by muse, mutect2, varscan2
- EBF1 | c.363G>A p.R121= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100565091; called by muse, mutect2, varscan2
- EDAR | c.1203C>T p.I401= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99303013; called by muse, mutect2, varscan2
- EFCAB6 | c.1050C>T p.T350= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as rs1301616149, COSV99412382; called by muse, mutect2, varscan2
- EIF4G1 | c.2943C>T p.D981= (on ENST00000346169 / NM_198241.3; = p.D786= on NM_004953.5) | Silent (SNP) | VAF 37/236 reads (16%) | catalogued as rs374422548; called by muse, mutect2, varscan2
- FBXL6 | c.921C>T p.T307= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV57352636; called by muse, mutect2, varscan2
- FCGBP | c.981G>A p.V327= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1478521186; called by muse, mutect2, varscan2
- FRMPD3 | c.2508C>T p.L836= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99345596; called by muse, mutect2, varscan2
- FXR1 | c.675G>A p.V225= | Silent (SNP) | VAF 13/155 reads (8%) | catalogued as COSV99976084; called by muse, mutect2
- GABRE | c.360C>T p.I120= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV100944308, COSV64819029; called by muse, mutect2, varscan2
- GPR160 | c.360T>C p.Y120= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs371080313, COSV63473632; called by muse, mutect2
- GPS1 | c.582C>T p.S194= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs375853187; called by mutect2, varscan2
- H2AC16 | c.78C>T p.F26= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as rs775619752, COSV100511086; called by muse, mutect2, varscan2
- H2AC20 | c.66T>A p.A22= | Silent (SNP) | VAF 40/193 reads (21%) | catalogued as COSV100479671; called by muse, mutect2, varscan2
- HDX | c.576C>T p.H192= | Silent (SNP) | VAF 31/194 reads (16%) | catalogued as rs149996033, COSV99946520; called by muse, mutect2, varscan2
- HNRNPR | c.990A>G p.E330= | Silent (SNP) | VAF 80/138 reads (58%) | catalogued as COSV100164293; called by muse, mutect2, varscan2
- ICA1 | c.525C>T p.D175= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as rs371492455, COSV99654808; called by muse, mutect2, varscan2
- INPP5E | c.717G>T p.P239= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV51528753, COSV99256045; called by muse, mutect2, varscan2
- JAK3 | c.1203C>T p.L401= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV101512875; called by muse, mutect2
- LMBRD1 | c.735G>A p.L245= (on ENST00000649011; = p.L223= on NM_018368.4) | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100992420; called by muse, mutect2, varscan2
- LRP1B | c.3891C>T p.F1297= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV101251917; called by muse, mutect2
- LRRC7 | c.1677G>A p.Q559= (on ENST00000651989 / NM_001370785.2; = p.Q526= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99224310, COSV99227682; called by muse, mutect2, varscan2
- LRRK2 | c.7371C>T p.V2457= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100109103; called by muse, mutect2, varscan2
- MATR3 | c.1731G>A p.L577= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100735098; called by muse, mutect2, varscan2
- MEX3A | c.1395C>T p.G465= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1311488251, COSV68479114; called by muse, mutect2
- NFE2L2 | c.1785C>T p.P595= | Silent (SNP) | VAF 11/176 reads (6%) | catalogued as COSV101229291; called by muse, mutect2
- NPTX2 | c.984C>T p.D328= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs781445701, COSV55719214; called by muse, mutect2, varscan2
- NUDT18 | c.699C>T p.A233= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as rs374856001; called by muse, mutect2, varscan2
- OR10G3 | c.246C>T p.L82= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1293200547, COSV100336057; called by muse, mutect2
- OR2T35 | c.672T>C p.T224= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100442140; called by mutect2, varscan2
- PATZ1 | c.1422G>A p.G474= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV99315069; called by muse, mutect2
- PCDHA6 | c.2034G>A p.A678= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs541356864, COSV65344768; called by muse, mutect2, varscan2
- PCSK1 | c.51C>T p.C17= | Silent (SNP) | VAF 40/194 reads (21%) | catalogued as rs774807858, COSV60733605; called by muse, mutect2, varscan2
- PHC2 | c.228G>A p.Q76= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99930671; called by muse, mutect2, varscan2
- PIK3CG | c.2814A>G p.A938= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as COSV100782491; called by muse, mutect2, varscan2
- PKHD1L1 | c.11958G>A p.K3986= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs369362762; called by muse, mutect2, varscan2
- PKIG | c.108G>A p.R36= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV100596064; called by muse, mutect2, varscan2
- PRR23B | c.315G>A p.L105= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs1439855967, COSV100271893; called by muse, mutect2
- RAPGEF2 | c.3783G>A p.Q1261= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV100030469; called by muse, mutect2, varscan2
- SEMA4D | c.1095G>A p.P365= | Silent (SNP) | VAF 30/39 reads (77%) | catalogued as rs779802450, COSV100357907; called by muse, mutect2, varscan2
- SLC44A2 | c.1377C>T p.F459= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as COSV59834966; called by muse, mutect2, varscan2
- SLC4A3 | c.3456G>A p.T1152= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs374261550; called by muse, mutect2, varscan2
- SPECC1 | c.1704C>T p.A568= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV54955979; called by muse, mutect2, varscan2
- SPRY2 | c.762A>G p.S254= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV101001656; called by muse, mutect2, varscan2
- SPTAN1 | c.825G>A p.E275= | Silent (SNP) | VAF 29/258 reads (11%) | catalogued as COSV63990651; called by muse, mutect2, varscan2
- TECPR1 | c.2982C>T p.I994= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs369865845; called by muse, varscan2
- TLK2 | c.1506G>A p.E502= (on ENST00000326270 / NM_001284333.2; = p.E480= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100408649, COSV58300214; called by muse, mutect2, varscan2
- TPH2 | c.1182G>A p.K394= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as COSV61592219; called by muse, mutect2, varscan2
- TRAPPC13 | c.57G>A p.L19= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99198813; called by muse, mutect2, varscan2
- TRPM1 | c.2805C>T p.I935= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs1302792652, COSV56643778, COSV99855277; called by muse, mutect2, varscan2
- VANGL2 | c.1329G>A p.A443= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs146767141; called by muse, mutect2, varscan2
- XPO4 | c.3348C>T p.L1116= | Silent (SNP) | VAF 24/240 reads (10%) | catalogued as COSV99687956; called by muse, mutect2
- ZNF292 | c.6279A>G p.K2093= | Silent (SNP) | VAF 53/86 reads (62%) | catalogued as COSV100369715; called by muse, mutect2, varscan2
- ZNF567 | c.1728C>G p.L576= (on ENST00000536254 / NM_001322913.1; = p.L545= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV100658624, COSV100658786, COSV62444859; called by muse, mutect2, varscan2
- ZNF711 | c.1374T>A p.A458= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99340614, COSV99341408; called by muse, mutect2, varscan2
- FADS1 | c.375+257C>T | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- MIR493 | n.43G>A | RNA (SNP) | VAF 9/68 reads (13%) | catalogued as rs768709644; called by muse, mutect2
